Gene-level copy-number profile of specimen HCM-SANG-0299-C15-85X from HCMI case HCM-SANG-0299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0299-C15-85X: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cd632d8a-25b3-4932-8d3d-c5bdd3b53e7b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0299-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,720 have no estimate.
https://portal.gdc.cancer.gov/files/a8a51615-7c16-4723-aa1c-8353870d3de6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,734; copy number 2: 21,414; copy number 3: 23,724; copy number 4: 10,032; copy number 5: 1,574; copy number 6: 303; copy number 7: 5; copy number 8: 9; copy number 9: 1; copy number 11: 9; copy number 13: 65; copy number 19: 8; copy number 22: 2; copy number 25: 3; copy number 35: 3; copy number 114: 17.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 122 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:7,991,134–8,026,309, 2 genes, copy number 8: AL034417.4, ERRFI1.
- chr1:8,878,835–8,894,151, 3 genes, copy number 7 (within-gene range 6–7): ENO1-AS1, RNU6-304P, HMGN2P17.
- chr1:8,979,576–9,026,345, 2 genes, copy number 7: RN7SL451P, SLC2A7.
- chr1:12,791,397–12,898,270, 8 genes, copy number 8–9: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10.
- chr12:22,609,228–28,978,685, 107 genes, copy number 11–114 (within-gene range 2–114) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,223. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
